Surgical pathology report (de-identified scan), TCGA case TCGA-78-7161, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7161-01A (Primary Tumor).

[page 1 of 2]
HISTORY

Lt upper lobe bronchial ca.

MACROSCOPIC

Four specimens received

1: The specimen is labelled 'left upper lobe' and consists of a lobe of lung (132 x 85 x 70), weighing 381 grams in the fixed state. Adherent to the visceral surface is a strip of parietal pleura measuring 127 x 52 mm. Within the parenchyma is a large cream tumour mass. The tumour comprises a relatively circumscribed cream nodule with areas of necrosis (57 mm in maximum diameter), merging with an ill-defined firm cream to tan area. The maximum diameter of the entire lesion (discrete nodule plus ill-defined area) measures 91 mm. The tumour invades visceral pleura and is adherent to parietal pleura. The discrete tumour nodule is 31 mm from the bronchial resection margin. The ill-defined lesion is 5 mm from the bronchial margin and extends to the hilar resection margin. Parenchyma distal to the tumour has a speckled yellow appearance. The minimal amount of uninvolved parenchyma away from the tumour is unremarkable. No other lesions are identified. [1A, bronchial resection margin; 1B, hilar lymph nodes; 1C, tumour with parietal pleura; 1D, discrete tumour nodule with adjacent ill-defined lesion; 1E, ill-defined area with adjacent uninvolved lung parenchyma; 1F, lesion involving bronchial wall, including hilar margin; 1G, lesion with hilar margin; 1H, parenchyma distal to tumour, with edge of tumour included; 1I-J, uninvolved lung parenchyma]

2: The specimen is labelled 'left lymph node no 5' and consists of two separate pieces of tan to grey nodal tissue measuring 15 x 11 x 12 mm and 12 x 6 x 4 mm. [Specimen BIT: 2A, larger piece trisected; 2B, smaller piece bisected]

3: The specimen is labelled 'left lymph node no 10' and consists of a single piece of tan to grey nodal tissue measuring 15 x 14 x 10 mm. [Trisected and BIT: 3A]

4: The specimen is labelled 'left no 10 lymph nodes' and consists of two separate pieces of nodal tissue measuring 14 x 6 x 6 mm and 7 x 5 x 2 mm. [Specimen BIT: 4A, larger node bisected; 4B, smaller node bisected]

MICROSCOPIC

DIAGNOSTIC SUMMARY: Moderately differentiated adenocarcinoma; Stage pT3N0; focal involvement of hilar soft tissue margin (R1); extension into parietal pleura.

CARCINOMA

1. Histological type: Adenocarcinoma; acinar and papillary patterns, with a smaller component of lepidic and solid. There is extensive necrosis.
2. Histological grade: Moderately differentiated
3. Tumour size: 91mm (macroscopic)

[page 2 of 2]
-
4. Pleural invasion: Tumour invades the visceral pleura and parietal pleura (Block 1C).
5. Vessel invasion: Not identified
6. Perineural invasion: Not identified
7. Carcinoma in situ: Not identified.

MARGINS

1. Bronchial margin:
- Invasive carcinoma: Clear (at least 4mm)
2. Vascular margin: Not identified.
3. Other margins: Adenocarcinoma focally extends to the hilar soft tissue margin (1G).
4. Residual tumour status: R1.
5. Contiguous structures: Present, parietal pleura.

LYMPH NODES

1. Peribronchial: There is no evidence of metastatic adenocarcinoma in hilar lymph nodes or in the other lymph nodes submitted (specimens 3-4).
2. Mediastinal: Not involved (specimen 2)

PATHOLOGICAL STAGE: pT3N0

NON-NEOPLASTIC LUNG: There is lipoid pneumonia and pulmonary oedema adjacent to the tumour. Moderate emphysematous change is identified. Focally, there is eccentric intimal thickening of blood vessels.

T-28000 M-81403 P1-03000

Source: NCI Genomic Data Commons file d50d8601-cd6a-47fc-ad06-b66516037f04 (TCGA-78-7161.0A86E747-A5E2-4D91-8EBD-6EF80E11CBC8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).